Somatic mutation profile of tumor specimen TARGET-10-PANZZI-09A (aliquot TARGET-10-PANZZI-09A-01D) from TARGET case TARGET-10-PANZZI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,123 days).
Specimen TARGET-10-PANZZI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dbe0a10-524a-4c9b-a068-9bd4b0737f5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANZZI-10A (Blood Derived Normal), aliquot TARGET-10-PANZZI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63275231-af25-4f86-97da-4f4777b91b22

The open-access MAF lists 13 somatic variants for this specimen: 3 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 3, RNA 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MN1 | c.2993C>T p.P998L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.211); catalogued as COSV100180086; called by muse, mutect2, varscan2
- MELTF | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ZNF618 | c.2470G>A p.E824K (on ENST00000374126 / NM_001318042.2; = p.E731K on NM_133374.2) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- BSDC1 | c.1224G>A p.V408= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs1430341501; called by muse, mutect2, varscan2
- L1CAM | c.630C>T p.H210= | Silent (SNP) | VAF 88/100 reads (88%) | catalogued as rs28933683, CM941029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB15 | c.1035G>A p.P345= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs1554291969, COSV51427231; called by muse, mutect2, varscan2
- TNXB | c.11178C>T p.F3726= (on ENST00000647633; = p.F3479= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs779290669, COSV64483375; called by muse, mutect2, varscan2
- TOGARAM2 | c.102G>A p.P34= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs201622059; called by muse, mutect2, varscan2
- USP48 | c.333G>A p.L111= | Silent (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2, varscan2
- AP002008.2 | n.2174C>T | RNA (SNP) | VAF 13/50 reads (26%) | catalogued as rs1451832134; called by muse, mutect2, varscan2
- HMGN2P46 | n.788C>A | RNA (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- KANSL3 | c.*2380G>C | 3'UTR (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- UGT2A1 | c.715+11189G>A | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as rs891728122; called by muse, mutect2
